Surgical pathology report (de-identified scan), TCGA case TCGA-EP-A3JL, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-EP-A3JL-01A (Primary Tumor).

[page 1 of 2]
Final Surgical Pathology Report

Procedure:

Diagnosis

- A. Submitted as lymph node, biopsy: Benign soft tissue; lymph node not identified.
- B. Gallbladder, cholecystectomy: Chronic cholecystitis.
- C. Liver, partial resection: Hepatocellular carcinoma, moderately-differentiated, 2.5 cm in greatest dimension without vascular invasion; negative margins of excision.

Microscopic Description:

Histologic type: Hepatocellular carcinoma
Histologic grade: Moderately-differentiated
Tumor size: Solitary tumor mass, 2.5 cm in greatest dimension
Primary tumor: pT1
Margins of resection: Negative (carcinoma is 5 mm from closest resection margin)
Vascular invasion: Negative
Regional lymph nodes (pN): None submitted
Distant metastasis (pM): Unknown

Comment: The presence of hepatocellular carcinoma (HCC) is confirmed by reticulin staining, which shows loss of the normal hepatic architecture with the nodular tumor, and by positive immunostaining by HepPar1. Stains for CK7, CK20, and CDX-2 are negative.

4, 3, 2, 18, 20x4

[A few of the antibodies used in our laboratory may be classified as analyte specific reagents. These antibodies are monitored and controlled in our laboratory and their performance for in vitro diagnosis is well described in the medical literature. They have not been cleared or approved by the FDA.]

Specimen

- A. Lymph node
- B. Gallbladder
- C. Liver mass

ICB-0-3
carcinoma, hepatocellular, NCC 8170/3
Site: liver C22.0 JW 12/8/11

Clinical Information

Liver cancer

Gross Description

- A. Received unfixed, labeled lymph node, is a 0.7 x 0.7 x 0.5 cm tan soft tissue fragment without discrete lymph node identified, entirely submitted in one block. AS1.
- B. Received in formalin labeled "gallbladder" is a 5.5 x 2.0 x 1.2 cm intact gallbladder. The serosa is pink-tan, smooth and glistening. The cystic duct is patent. The specimen is opened and partially filled with green-brown viscid bile. The mucosa is pink-tan and velvety. No choleliths are identified in the specimen or the specimen container. The average wall thickness is 0.3 cm. Greater than 50% of the specimen is submitted in 2 cassettes including cystic duct which is inked. RS 2.

[page 2 of 2]
C. Received unfixed for tissue procurement, labeled liver mass, is a 5 x 5 x 4 cm wedge-shaped partial liver resection specimen, with cauterized surface. There is a nodular, firm tan mass lesion, 2.5 cm in greatest dimension and 0.5 cm from the resection margin. A portion of tumor and uninvolved liver tissue is submitted for tissue procurement. Representative sections in 4 blocks.

Source: NCI Genomic Data Commons file a9271a26-b464-466b-a437-e4768b7ec58d (TCGA-EP-A3JL.B277ACF9-B233-474B-975A-52FDE44F27E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).